Somatic mutation profile of tumor specimen 0DT3UE from CCDI case PBCJCW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (654 days).
Specimen 0DT3UE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 961141d0-96af-4ff0-b223-d740109c3454.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT3US (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1b2c0fd-e1af-40a7-9554-da048389ec07

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Intron 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAAP100 | c.2353G>A p.V785M | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs775175481, COSV100585460; called by muse, mutect2, varscan2
- SCAF1 | c.831_848del p.E277_E282del | In Frame Del (DEL) | VAF 92/252 reads (37%) | catalogued as rs770091979; called by mutect2, varscan2
- SETD1B | c.4202C>T p.P1401L | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs550283601; called by muse, mutect2, varscan2
- TCF12 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs758487665; called by muse, mutect2, varscan2
- CNOT3 | c.2095C>T p.H699Y | Missense Mutation (SNP) | VAF 419/723 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AFF2 | c.1989T>C p.L663= | Silent (SNP) | VAF 36/588 reads (6%) | called by muse, mutect2
- AMMECR1 | c.339C>T p.A113= | Silent (SNP) | VAF 21/255 reads (8%) | catalogued as rs1273784689; called by muse, mutect2
- MTFR1 | c.402G>A p.A134= | Silent (SNP) | VAF 152/396 reads (38%) | catalogued as rs139624623; called by muse, mutect2, varscan2
- OR2M5 | c.405C>T p.L135= | Silent (SNP) | VAF 88/762 reads (12%) | called by muse, mutect2, varscan2
- PRIMA1 | c.-14C>T | 5'UTR (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100301116; called by muse, mutect2, varscan2
- TTC12 | c.-16+439C>T | Intron (SNP) | VAF 12/102 reads (12%) | catalogued as rs1239757679; called by muse, mutect2
